Surgical pathology report (de-identified scan), TCGA case TCGA-28-1746, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-1746-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT******* Addendum - Please See End of Report *******

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:**A, G, H. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:**

- Glioblastoma multiforme, WHO grade IV

B. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor - 95%
- Proportion of necrosis - 10%

C. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor - 100%
- Proportion of necrosis - 30%

D. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor - 100% of cortex and white matter infiltrated by the tumor
- Proportion of necrosis - 0%

E. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor - 100%
- Proportion of necrosis - 25%

F. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV
- Proportion of the tumor - 100%
- Proportion of necrosis - 0%

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar [REDACTED]. Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Patient Case(s):

[page 2 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED] PATH #:

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas. [REDACTED] between laminin-8 and glial tumor grade, recurrence, and patient survival. [REDACTED] Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED] Molecular subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) has been shown to be associated with a relative resistance of glioblastoma multiforme to radiation therapy.

[REDACTED] Prognostic Associations of Activated Mitogen-Activated Protein Kinase and Akt Pathways in Glioblastoma. [REDACTED]

Correspondingly, presence of a large fraction of cells immunonegative to pMAPK antibody in this case suggests a likelihood of this tumor being responsive to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

IDC2a: Selected slides were reviewed in consultation with

HISTORY: Temporal tumor

MICROSCOPIC:

Sections disclose necrotizing malignant neoplasm featuring striking microvascular proliferation and composed of diffuse infiltration of hyperchromatic elongate astrocytic nuclei showing numerous mitotic figures. The tumor displays extensive infiltration with focal extension to the pia.

IMMUNOSTAINS:

MGMT (G3): 3%

PTEN (G3): Loss (1+)

pMAPK (G3): 10% of tumor nuclei and 15% of tumor cell cytoplasm is positive

Laminin beta-1 (8/411) (G3): Upregulated (3+ in endothelial cells)

Laminin beta-2 (9/421) (G3): Focal loss (0-1+ staining in endothelial cells)

GROSS:

A. RIGHT TEMPORAL TUMOR FS

Labeled with the patient's name, labeled "right temporal", and received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin is a 1.5 x 2.1 x 0.4 cm aggregate of multiple pink-tan soft tissue fragments ranging from 0.1 to 1.1 cm in greatest dimension. Entirely submitted.

A1. Frozen section remnant - 1

A2. Remaining tissue - multiple

B. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal", and received in formalin is a 0.9 x 0.4 x 0.3 cm pink-tan soft tissue fragment. Entirely embedded.

[page 3 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED] PATH #:

Slide key:

B1. Frozen section remnant - 1

C. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal", and received in formalin is a 0.5 x 0.4 x 0.2 cm pink-gray soft tissue fragments. Entirely embedded.

C1. 1

D. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal", and received in formalin is a 0.4 x 0.2 x 0.3 cm gray-tan soft tissue fragment. Entirely embedded.

Slide key:

D1. 1

E. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal", and received in formalin are two soft pink-tan tissue fragments measuring 0.4 x 0.2 x 0.1 cm and 0.5 x 0.4 x 0.1 cm. Entirely embedded.

E1. 2

F. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal", and received in formalin is a 0.5 x 0.4 x 0.1 cm pink-gray soft tissue fragment. Entirely submitted.

F1. 1

G. RIGHT TEMPORAL/PERMANENT

Labeled with the patient's name, labeled "right temporal", and received in formalin is a 4.2 x 3.5 x 1.5 cm aggregate of multiple pink-gray soft tissue fragments with focal areas of hemorrhage on their surfaces. The segments range in size from 0.1 cm to 2.4 cm in greatest dimension. Entirely embedded.

Slide key:

G1. 4

G2. 3

G3. Multiple

G4. 3

H. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal tumor", and received in formalin is a 3.5 x 4.0 x 1.8 cm aggregate of multiple pink-tan soft tissue fragments ranging from 0.5 to 3.2 cm in greatest dimension. Along the outer surfaces of the fragment are focal areas of hemorrhage. Entirely embedded.

H1. 4

H2. 2

H3. 4

H4. 2

Gross dictated by
[REDACTED]

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

PART A. RIGHT TEMPORAL FS:

- Glioblastoma

[page 4 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED] PATH #:

[REDACTED]

If this report includes immunohistochemical test results, please note the following:

Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] of Pathology and Laboratory Medicine. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Electronically signed [REDACTED]

***ADDENDUM [REDACTED]**

FISH (FLUORESCENCE IN SITU HYBRIDIZATION) for EGFR

RESULTS:**Number of cells analyzed: 40****Ratio of EGFR/CEP: 1.1****Percentage of cells with ≥ 4 copies of EGFR: 72.5%****Amplification: NO****High Level of Polysomy: YES****INTERPRETATION:**

1. Samples are interpreted as Positive if :
- a. EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells.
- b. When high level of polysomy ($\geq$ four copies of EGFR in $\geq 40\%$ of cells) is present.
2. Samples are interpreted as Negative if EGFR to CEP 7 signal ratio is < 2.0 or in the absence of high level of polysomy ($\geq$ four copies of EGFR).
3. Samples are considered inconclusive, requiring consult with the pathologist, when EGFR to CEP 7 signal ratio is ≥ 2.0 in $< 10\%$ of analyzed cells or when high level of polysomy ($\geq$ four copies of EGFR) is present in $< 40\%$ of cells. These cases also need to be co-read.

[page 5 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED] PATH #:

REFERENCES

TCGA-28-1746

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed [REDACTED]

Source: NCI Genomic Data Commons file b8d629b0-e22c-47c1-bcfa-2c0c3c8250f4 (TCGA-28-1746.2ABF3D8F-18F6-493D-89B8-3E2A5F37F84E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).